Gene-level copy-number profile of tumor specimen ALCH-B278-TTP1-A from ALCHEMIST case ALCH-B278, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.6 years (20,303 days).
Specimen ALCH-B278-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1cf8a62-966a-47f7-8513-addd0fd87f11.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B278-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,272 have no estimate.
https://portal.gdc.cancer.gov/files/e91da011-4f41-4658-835e-f9e1f5cd4886

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 104; copy number 2: 31,861; copy number 3: 24,581; copy number 4: 1,553; copy number 5: 150; copy number 6: 22; copy number 7: 59; copy number 8: 6; copy number 10: 14; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 243 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,155,961, 8 genes, copy number 7 (within-gene range 1–7): PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF26.
- chr1:162,631,373–162,787,405, 1 gene, copy number 5 (within-gene range 4–5): DDR2.
- chr2:90,114,838–90,115,402, 1 gene, copy number 6 (within-gene range 3–6): IGKV3D-15.
- chr2:90,309,230–90,367,699, 4 genes, copy number 5–8: AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr2:225,399,710–225,762,112, 4 genes, copy number 5–6: NYAP2, AC016717.1, AC016717.2, AC016717.3.
- chr5:10,337,277–10,343,131, 2 genes, copy number 5: Y_RNA, AC012640.5.
- chr5:40,759,379–40,798,374, 2 genes, copy number 5: PRKAA1, AC008810.1.
- chr6:41,026,895–41,406,561, 23 genes, copy number 5: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2.
- chr6:41,636,882–42,217,861, 28 genes, copy number 5: MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10.
- chr6:42,499,710–44,553,281, 87 genes, copy number 5–8 (broad region; genes not listed).
- chr8:39,451,045–39,522,852, 1 gene, copy number 5: ADAM3A.
- chr8:39,860,219–39,928,790, 3 genes, copy number 5 (within-gene range 4–5): AP005902.2, AP005902.1, IDO1.
- chr8:39,914,229–39,920,890, 2 genes, copy number 5 (within-gene range 4–5): AC007991.2, AC007991.4.
- chr9:66,635,754–66,642,277, 2 genes, copy number 5: RBPJP2, RAB28P4.
- chr10:4,650,158–5,404,828, 23 genes, copy number 5–7: MANCR, LINC00705, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3.
- chr10:30,380,174–30,580,182, 9 genes, copy number 5: NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2.
- chr10:31,805,398–32,056,839, 6 genes, copy number 5: ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA.
- chr10:34,926,775–34,943,075, 2 genes, copy number 5: RNU6-847P, RNU6-193P.
- chr11:65,375,192–65,383,701, 1 gene, copy number 5 (within-gene range 2–5): SLC25A45.
- chr15:21,127,698–21,130,095, 1 gene, copy number 14: AC126335.1.
- chr19:41,750,977–41,852,333, 7 genes, copy number 7 (within-gene range 3–7): CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2.
- chr20:31,514,410–31,801,805, 14 genes, copy number 10: HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:31,944,337–32,170,790, 11 genes, copy number 5 (within-gene range 4–5): PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6.
- chr22:30,182,818–30,207,195, 1 gene, copy number 5: AC002378.1.

Autosomal genes at a single copy (total copy number 1): 103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
